Somatic mutation profile of tumor specimen TCGA-AK-3444-01A (aliquot TCGA-AK-3444-01A-01W-0886-08) from TCGA case TCGA-AK-3444, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.8 years (29,497 days).
Specimen TCGA-AK-3444-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 382bd1a9-e03b-44e5-8ffc-768239c5d095.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3444-10A (Blood Derived Normal), aliquot TCGA-AK-3444-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28a1ae1d-3612-4943-bd29-2b85ce6c3f5a

The open-access MAF lists 110 somatic variants for this specimen: 81 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 24, Frame Shift Del 7, Frame Shift Ins 4, In Frame Del 3, Intron 3, Nonsense Mutation 2, Splice Site 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3292C>T p.Q1098* | Nonsense Mutation (SNP) | VAF 8/174 reads (5%) | catalogued as COSV61372190; called by muse, mutect2
- BACE2 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1439528201; called by muse, mutect2, varscan2
- CFAP221 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 155/718 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV54654135, COSV99732337; called by muse, mutect2, varscan2
- CTAGE1 | c.1284dup p.A429Sfs*3 | Frame Shift Ins (INS) | VAF 19/68 reads (28%) | catalogued as rs756054046; called by mutect2, pindel, varscan2
- CX3CR1 | c.834del p.E279Rfs*10 | Frame Shift Del (DEL) | VAF 42/382 reads (11%) | catalogued as COSV100843329; called by mutect2, varscan2
- EHHADH | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 126/397 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.254); catalogued as rs1158697281, COSV51631804; called by muse, mutect2, varscan2
- ERBB4 | c.1778G>T p.C593F | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53529587; called by muse, mutect2, varscan2
- GIMAP8 | c.1192G>C p.A398P | Missense Mutation (SNP) | VAF 110/558 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV56232964; called by muse, mutect2, varscan2
- HLF | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779590300, COSV56831389; called by muse, mutect2, varscan2
- KALRN | c.4724T>G p.I1575S | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99567440; called by muse, mutect2, varscan2
- LIPE | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 79/320 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs376903518; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 49/347 reads (14%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP6 | c.4367G>A p.S1456N | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.347); catalogued as rs367658176; called by muse, mutect2
- MEGF8 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.341); catalogued as rs1381630142; called by muse, mutect2, varscan2
- MLC1 | c.312C>A p.N104K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.358); catalogued as rs763564142, COSV61116059; called by muse, mutect2, varscan2
- NID2 | c.4093G>A p.A1365T | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs201207693; called by muse, mutect2, varscan2
- NUDT19 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV67959602; called by muse, mutect2
- PCDHGA3 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as COSV53930602; called by muse, mutect2, varscan2
- POU6F2 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 31/650 reads (5%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as COSV68866982; called by muse, mutect2
- PZP | c.4075G>C p.D1359H | Missense Mutation (SNP) | VAF 91/331 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV54356689; called by muse, mutect2, varscan2
- RNASEH2A | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CD150565; called by muse, mutect2, varscan2
- SAP130 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 208/964 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); catalogued as rs1477417985; called by muse, mutect2, varscan2
- SLC2A4RG | c.531dup p.E178Rfs*56 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | catalogued as rs748002768; called by pindel, varscan2
- SOS1 | c.625A>C p.M209L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV101216948; called by muse, mutect2, varscan2
- TMIGD2 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV100010403, COSV56667447; called by muse, mutect2
- UMODL1 | c.1520-1G>A p.X507_splice | Splice Site (SNP) | VAF 39/142 reads (27%) | catalogued as COSV61159573; called by muse, mutect2, varscan2
- WDR5 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62272626; called by muse, mutect2, varscan2
- ALG6 | c.1336_1341del p.S446_V447del | In Frame Del (DEL) | VAF 115/401 reads (29%) | called by mutect2, pindel, varscan2
- ANKMY1 | c.847T>C p.F283L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1B | c.4776del p.I1593Sfs*8 | Frame Shift Del (DEL) | VAF 47/204 reads (23%) | called by mutect2, pindel, varscan2
- ASXL1 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- B3GNT5 | c.197A>G p.H66R | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARS2 | c.618del p.K206Nfs*71 | Frame Shift Del (DEL) | VAF 118/397 reads (30%) | called by mutect2, pindel, varscan2
- CNTN1 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- COL12A1 | c.7367T>A p.F2456Y | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL15A1 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCAKD | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DLGAP3 | c.1183_1188del p.G395_S396del | In Frame Del (DEL) | VAF 123/312 reads (39%) | called by mutect2, pindel, varscan2
- DNAH5 | c.4177G>T p.G1393C | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DYNC1H1 | c.13688T>G p.L4563W | Missense Mutation (SNP) | VAF 146/367 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYSF | c.6073T>A p.F2025I | Missense Mutation (SNP) | VAF 146/646 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERICH6 | c.1096C>A p.H366N | Missense Mutation (SNP) | VAF 89/387 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERVW-1 | c.1119C>A p.N373K | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, varscan2
- FGFR4 | c.2336A>C p.D779A | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRMPD1 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- GJD2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- GNB1 | c.645A>C p.E215D | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR89B | c.1097T>A p.F366Y | Missense Mutation (SNP) | VAF 256/945 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- IDS | c.83C>G p.T28R | Missense Mutation (SNP) | VAF 132/361 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- INCENP | c.1475T>C p.L492P | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KLF17 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- KRT39 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 94/993 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- MCTP2 | c.2287A>G p.M763V | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAV3 | c.512C>G p.A171G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NEB | c.13134dup p.K4379* | Frame Shift Ins (INS) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- NOC3L | c.926del p.L309Wfs*16 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- OR51E1 | c.946T>G p.S316A | Missense Mutation (SNP) | VAF 242/700 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHKA2 | c.625_636del p.L209_I212del | In Frame Del (DEL) | VAF 121/462 reads (26%) | called by mutect2, pindel, varscan2
- PHLDB2 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 28/1088 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.64); called by muse, mutect2
- PIK3R4 | c.3640G>C p.D1214H | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- PMS2 | c.1081G>C p.G361R | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- POLE | c.3760del p.I1254Sfs*107 | Frame Shift Del (DEL) | VAF 125/447 reads (28%) | called by mutect2, pindel, varscan2
- POLR3B | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRRC2C | c.2521G>A p.D841N (on ENST00000367742; = p.D839N on NM_015172.4) | Missense Mutation (SNP) | VAF 101/385 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PTPN22 | c.751-1G>T p.X251_splice | Splice Site (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- RALBP1 | c.331del p.V111Ffs*17 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel
- SLC17A6 | c.376A>C p.M126L | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX11 | c.596A>C p.E199A | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2
- SSUH2 | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ST8SIA1 | c.903T>A p.N301K | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SYNJ2 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAGAP | c.1625del p.G542Vfs*30 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | called by mutect2, pindel, varscan2
- TGM5 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 126/406 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM184C | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 53/459 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TMEM61 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOP3A | c.1867A>T p.K623* | Nonsense Mutation (SNP) | VAF 74/198 reads (37%) | called by muse, mutect2, varscan2
- TTN | c.52648T>C p.F17550L (on ENST00000591111; = p.F10126L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | PolyPhen benign (0.024); called by muse, mutect2, varscan2
- VSIG4 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 205/615 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- WSCD1 | c.1550T>A p.L517Q | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB10 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ZFC3H1 | c.3230T>A p.V1077E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.034); called by muse, mutect2
- AP5Z1 | c.1935C>T p.S645= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs759141046; called by mutect2, varscan2
- CADM1 | c.441G>A p.L147= | Silent (SNP) | VAF 111/360 reads (31%) | called by muse, mutect2, varscan2
- CDSN | c.513G>C p.G171= | Silent (SNP) | VAF 48/137 reads (35%) | called by muse, mutect2, varscan2
- CES2 | c.1200C>G p.P400= | Silent (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- DGKI | c.2076G>T p.R692= | Silent (SNP) | VAF 53/782 reads (7%) | called by muse, mutect2
- E2F8 | c.198C>T p.L66= | Silent (SNP) | VAF 35/422 reads (8%) | catalogued as rs763610653; called by muse, mutect2
- EPCAM | c.96C>T p.Y32= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- FAM120B | c.612C>T p.V204= | Silent (SNP) | VAF 39/129 reads (30%) | called by muse, mutect2, varscan2
- FBXO9 | c.396T>C p.T132= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- GDI2 | c.1002C>G p.V334= | Silent (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- HEPHL1 | c.411A>C p.S137= | Silent (SNP) | VAF 51/165 reads (31%) | called by muse, mutect2, varscan2
- MYORG | c.1218G>A p.V406= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- OGA | c.684G>A p.V228= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV63383265; called by muse, mutect2, varscan2
- OR2AG1 | c.717C>T p.V239= | Silent (SNP) | VAF 16/255 reads (6%) | catalogued as rs770528715; called by muse, mutect2
- OR9G1 | c.567C>T p.G189= | Silent (SNP) | VAF 24/364 reads (7%) | catalogued as rs770442188, COSV56448164; called by muse, mutect2
- PFKP | c.978A>G p.G326= | Silent (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- PGLYRP4 | c.1101C>G p.T367= | Silent (SNP) | VAF 143/502 reads (28%) | called by muse, mutect2, varscan2
- SAP130 | c.1047T>C p.S349= | Silent (SNP) | VAF 208/968 reads (21%) | called by muse, mutect2, varscan2
- SPATA5 | c.591G>A p.G197= | Silent (SNP) | VAF 20/158 reads (13%) | called by muse, mutect2, varscan2
- SPINT1 | c.36C>T p.L12= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs557336289; called by muse, mutect2
- SRBD1 | c.6A>T p.S2= | Silent (SNP) | VAF 130/292 reads (45%) | called by muse, mutect2, varscan2
- STAG3 | c.2787G>A p.L929= | Silent (SNP) | VAF 111/392 reads (28%) | called by muse, mutect2, varscan2
- STAG3 | c.2788C>T p.L930= | Silent (SNP) | VAF 107/386 reads (28%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.306C>T p.C102= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as CM035575; called by muse, varscan2
- AKR1D1 | c.690-173C>T | Intron (SNP) | VAF 11/60 reads (18%) | catalogued as rs539301673, COSV99652871; called by muse, mutect2, varscan2
- HERC2P3 | n.1914A>G | RNA (SNP) | VAF 48/106 reads (45%) | called by mutect2, varscan2
- MICAL3 | c.2241+1592dup | Intron (INS) | VAF 5/41 reads (12%) | catalogued as rs764722045; called by pindel, varscan2
- PRR12 | chr19:49594891 C>A | 5'Flank (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- RGS3 | c.3081-333G>C | Intron (SNP) | VAF 14/39 reads (36%) | catalogued as rs765245767; called by muse, mutect2, varscan2
